CCDI case PBCJLZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of limbs.
https://portal.gdc.cancer.gov/cases/9f67753a-571c-4675-bb58-9bd4b3d42404

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Undifferentiated sarcoma: ICD-O-3 morphology code: 8805/3; Tissue or organ of origin: Lower limb, NOS; Age at diagnosis: 13.2 years (4,830 days).

Biospecimens (3 samples)
- Samples 0DTC5O, 0DTC64 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DTC5W: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
